Somatic mutation profile of tumor specimen MMRF_2622_1_BM_CD138pos (aliquot MMRF_2622_1_BM_CD138pos_T1_KHS5U_L12863) from MMRF case MMRF_2622, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.7 years (21,814 days).
Specimen MMRF_2622_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4ed4e6-220f-408d-b286-2ebd4fbcb97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2622_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2622_1_PB_Whole_C3_KHS5U_L12864; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05306a7d-1f5a-4cab-91e9-353e24bb1ab5

The open-access MAF lists 93 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 19, Intron 12, Silent 11, 5'UTR 6, Nonsense Mutation 4, 5'Flank 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTG2 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1226653208, COSV99305916; called by muse, mutect2
- CACNA1C | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV59708544; called by muse, mutect2
- CDH19 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs755450134, COSV50956016; called by muse, mutect2, varscan2
- IGHV2-70D | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1446744170; called by mutect2, varscan2
- INSRR | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1275032854; called by muse, mutect2, varscan2
- MGARP | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 43/183 reads (23%) | catalogued as rs373418814; called by muse, mutect2, varscan2
- NFKBIE | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs765482726; called by muse, mutect2, varscan2
- POLR2H | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs1234674745; called by muse, mutect2, varscan2
- RNF182 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as rs201967624, COSV70369087; called by muse, mutect2, varscan2
- SCUBE3 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as rs978504252, COSV51459526; called by muse, mutect2, varscan2
- TENT5C | c.958T>C p.C320R | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65616233; called by muse, mutect2, varscan2
- TTC28 | c.6220C>T p.R2074* | Nonsense Mutation (SNP) | VAF 9/146 reads (6%) | catalogued as rs1371756457; called by muse, mutect2
- ZNF729 | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV62603452; called by muse, mutect2
- AAMP | c.410T>G p.V137G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADARB1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ALMS1 | c.5810C>A p.P1937H | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CCDC172 | c.255C>A p.N85K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUX2 | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DCAF8 | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIS3 | c.2325T>G p.F775L | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.6080T>C p.I2027T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIP1R | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGSF11 | c.580+2T>C p.X194_splice (on ENST00000393775 / NM_001015887.3; = p.X193_splice on NM_152538.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- LDHB | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- LINS1 | c.2237T>C p.I746T | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MGAT4B | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NBEAL2 | c.5558A>G p.E1853G | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- OR4A47 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PALLD | c.2985T>A p.D995E (on ENST00000505667 / NM_001166108.2; = p.D978E on NM_016081.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA10 | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R12B | c.2885A>G p.D962G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PPP1R21 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2, varscan2
- RBP3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPICE1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- STARD13 | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5C | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- THADA | c.1237A>C p.I413L | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC8 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5C | c.252A>T p.K84N | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AHNAK2 | c.16848T>C p.P5616= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- AIRE | c.1320T>C p.G440= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1365717395; called by mutect2, varscan2
- FAM20A | c.660C>G p.V220= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- IQSEC3 | c.2670G>A p.A890= (on ENST00000538872 / NM_001170738.2; = p.A587= on NM_015232.1) | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs782121610, COSV58280065; called by muse, mutect2, varscan2
- KCNK13 | c.1122C>T p.C374= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- KRT40 | c.399C>T p.C133= | Silent (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- MYH6 | c.4998C>T p.N1666= | Silent (SNP) | VAF 36/308 reads (12%) | catalogued as rs371361552; called by muse, mutect2, varscan2
- OR4N2 | c.633T>C p.F211= | Silent (SNP) | VAF 80/372 reads (22%) | catalogued as COSV60051405; called by muse, mutect2, varscan2
- PDE6B | c.1389C>A p.I463= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV55324761; called by muse, mutect2, varscan2
- RLN1 | c.517C>T p.L173= | Silent (SNP) | VAF 90/248 reads (36%) | called by muse, mutect2, varscan2
- ZIM2 | c.531C>T p.T177= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs529440942; called by muse, mutect2, varscan2
- ADAM28 | c.47-50G>C | Intron (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2
- AGPAT4 | c.348+4824T>A | Intron (SNP) | VAF 79/260 reads (30%) | called by muse, mutect2, varscan2
- AMDHD1 | c.*587C>A | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- AP3B2 | c.1379-58C>T | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- ARHGEF12 | c.*2843T>C | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- BRD2 | c.-706G>C | 5'UTR (SNP) | VAF 20/166 reads (12%) | catalogued as rs955305019; called by muse, mutect2, varscan2
- CATSPERD | c.-12A>G | 5'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- CCDC180 | c.3903-479T>G | Intron (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- CD300E | c.*2435A>T | 3'UTR (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- CLDN1 | c.*854T>G | 3'UTR (SNP) | VAF 39/130 reads (30%) | called by muse, mutect2, varscan2
- COPS4 | c.1088-1950A>C | Intron (SNP) | VAF 35/180 reads (19%) | called by muse, mutect2, varscan2
- DHX35 | c.*990T>A | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- DXO | c.-35T>A | 5'UTR (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- FAM118A | c.522+804C>G | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- GRK6 | chr5:177426565 A>C | 5'Flank (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- H2AC17 | c.*9C>T | 3'UTR (SNP) | VAF 74/260 reads (28%) | called by muse, mutect2, varscan2
- HLCS | c.*1824C>T | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- LINS1 | c.*139T>C | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, varscan2
- MAP3K4 | c.4236+64T>A | Intron (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- MFSD14B | c.*739A>G | 3'UTR (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- MSRB3 | c.*1293T>C | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- MYT1L | c.*1835G>A | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- NCSTN | chr1:160343366 A>C | 5'Flank (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.*142C>A | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- NONO | c.944-100A>G | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- NSDHL | c.*307T>G | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- PDZD3 | c.*227A>T | 3'UTR (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- PYGB | c.*1380T>C | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- RABGAP1L | c.-28T>C | 5'UTR (SNP) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- RABGAP1L | c.-17del | 5'UTR (DEL) | VAF 14/48 reads (29%) | catalogued as rs746792237; called by mutect2, varscan2
- S100A7A | chr1:153421758 C>A | 3'Flank (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- SETD7 | c.*5232A>G | 3'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as rs140877165; called by muse, mutect2, varscan2
- SINHCAF | c.-21+891A>G | Intron (SNP) | VAF 18/124 reads (15%) | catalogued as rs1206475945; called by muse, mutect2, varscan2
- SNX13 | c.441-5595T>C | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+1018A>G | Intron (SNP) | VAF 55/161 reads (34%) | called by muse, mutect2, varscan2
- TEX15 | c.*1654T>C | 3'UTR (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- TMEM198 | c.*593del | 3'UTR (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- TMEM30A | c.*912C>T | 3'UTR (SNP) | VAF 25/73 reads (34%) | catalogued as rs986877815; called by muse, mutect2, varscan2
- WTAP | c.-40G>A | 5'UTR (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2
- ZIC4 | c.-15-1178del | Intron (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
